Gene-level copy-number profile of tumor specimen HCM-CSHL-0090-C25-01A from HCMI case HCM-CSHL-0090-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 64.8 years (23,666 days).
Specimen HCM-CSHL-0090-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 383de1d7-cd26-4d22-adf8-efef4c42f809.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0090-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/5c66b674-65f3-4409-b8bd-3bfdd65f8acc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 271; copy number 2: 12,221; copy number 3: 28,839; copy number 4: 13,227; copy number 5: 1,649; copy number 6: 1,399; copy number 7: 659; copy number 8: 98; copy number 9: 27; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 785 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–38,631,420, 673 genes, copy number 7–9 (broad region; genes not listed).
- chr7:144,142,009–144,410,227, 17 genes, copy number 7: OR2A13P, OR2A3P, OR2AO1P, CTAGE4, ARHGEF35, ARHGEF35-AS1, OR2A42, OR2A20P, AC074386.1, OR2A7, CTAGE8, ARHGEF34P, OR2A9P, OR2A1-AS1, OR2A1, ARHGEF5, NOBOX.
- chr7:147,146,342–147,167,572, 2 genes, copy number 8: DUTP3, RANP2.
- chr7:147,831,770–147,940,301, 3 genes, copy number 8: RNU6-1184P, RNA5SP249, RN7SL456P.
- chr7:148,807,383–150,076,655, 43 genes, copy number 8: EZH2, RNU7-20P, Metazoa_SRP, RN7SL569P, RNY4, RNY3, RNY1, GHET1, PDIA4, RNU6-650P, COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746, ZNF767P, KRBA1, ZNF467, SSPOP, ZNF862, AC004877.2, AC004877.1, ATP6V0E2-AS1, ATP6V0E2, AC093458.1, AC093458.2, AC092681.3, AC092681.1, AC092681.2, AC092666.1, AC092666.2.
- chr7:151,556,124–152,019,929, 7 genes, copy number 8: PRKAG2, AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1, GALNTL5.
- chr7:153,887,097–156,263,802, 39 genes, copy number 8: DPP6, AC005588.1, AC006019.3, AC006019.1, AC006019.2, AC024730.1, AC073336.1, PAXIP1-AS2, PAXIP1, AC093726.1, AC093726.2, PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.1, RBM33, SHH, AC021218.1, Y_RNA, AC093813.1.
- chr9:67,512,034–67,515,393, 1 gene, copy number 18: BX664730.1.

Autosomal genes at a single copy (total copy number 1): 271. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
